Somatic mutation profile of tumor specimen MMRF_1766_1_BM_CD138pos (aliquot MMRF_1766_1_BM_CD138pos_T1_KBS5U_L05769) from MMRF case MMRF_1766, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,210 days).
Specimen MMRF_1766_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7842a37f-c550-4079-9305-a2fda033a61c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1766_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1766_1_PB_Whole_C3_KBS5U_L05793; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b913d64-14d8-4b97-bc78-93d15bdd8dfd

The open-access MAF lists 114 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 20, Silent 19, Intron 14, 3'Flank 4, Nonsense Mutation 4, 5'UTR 4, RNA 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 129/304 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.686C>G p.T229S (on ENST00000676605; = p.T188S on NM_024790.6) | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.051); catalogued as COSV51588134; called by muse, mutect2, varscan2
- FAM155A | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.127); catalogued as COSV101027584; called by muse, mutect2, varscan2
- H1-3 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749549303, COSV55098009; called by muse, mutect2, varscan2
- IFT122 | c.3047G>A p.R1016Q (on ENST00000348417 / NM_052989.3; = p.R957Q on NM_018262.4) | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs758998922, COSV99959427; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGHV2-70 | c.96A>C p.K32N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957766; called by muse, varscan2
- IGHV3-21 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.047); catalogued as rs374206854; called by muse, mutect2
- IGLV3-25 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs373903585; called by muse, mutect2, varscan2
- IRAG2 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.234); catalogued as rs1246932095; called by muse, mutect2, varscan2
- L3MBTL1 | c.520C>T p.P174S (on ENST00000418998 / NM_001377303.1; = p.P84S on NM_015478.7) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV64231147; called by muse, mutect2, varscan2
- MAP3K6 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs754114751, COSV62887490; called by muse, mutect2, varscan2
- NLRP3 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs543916695; called by muse, mutect2, varscan2
- PAK4 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1267698343; called by muse, mutect2, varscan2
- PANK4 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1209627355; called by muse, mutect2, varscan2
- RCOR2 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1331366404, COSV100036413; called by muse, mutect2, varscan2
- SLC25A47 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.464); catalogued as rs201144508, COSV59927123; called by muse, mutect2, varscan2
- SLC26A4 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749479853, COSV55914647; called by muse, mutect2, varscan2
- ST3GAL2 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | PolyPhen benign (0.413); catalogued as rs779489877; called by muse, mutect2, varscan2
- TENT5C | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65616287; called by muse, mutect2, varscan2
- TRIM17 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs746701267, COSV52858696; called by mutect2, varscan2
- ADGRF5 | c.555C>A p.D185E | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ADGRL1 | c.780C>G p.Y260* (on ENST00000340736 / NM_001008701.3; = p.Y255* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 68/227 reads (30%) | called by muse, mutect2, varscan2
- AGR3 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- APOB | c.811T>A p.S271T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AQP9 | c.781A>T p.I261F | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CACNA1C | c.1996T>C p.S666P | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD36 | c.1399A>T p.R467* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- CROCC2 | c.4356G>T p.L1452F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DHCR24 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- DRC3 | c.992A>T p.H331L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ELOVL6 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- EMC6 | c.237A>T p.K79N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- FZD6 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- KDM4D | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- LIMCH1 | c.2129C>A p.S710* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- MAN2C1 | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MMP2 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5W2 | c.796T>A p.Y266N | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PARG | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- SLITRK1 | c.105A>T p.E35D | Missense Mutation (SNP) | VAF 93/214 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TBC1D8 | c.1849T>G p.C617G | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX45 | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- WDR72 | c.2737A>C p.K913Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.154); called by muse, mutect2
- ZC3H15 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ANKRD18A | c.714T>C p.D238= | Silent (SNP) | VAF 61/214 reads (29%) | called by muse, mutect2, varscan2
- CDH12 | c.2199C>T p.Y733= | Silent (SNP) | VAF 60/216 reads (28%) | catalogued as rs746650644, COSV66424640; called by muse, mutect2, varscan2
- ERCC1 | c.51A>C p.P17= | Silent (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs376111067; called by muse, varscan2
- IGKJ5 | c.6C>T p.I2= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as rs367938025; called by muse, varscan2
- IGSF8 | c.117C>A p.R39= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV58759478; called by muse, mutect2, varscan2
- IQUB | c.864G>A p.T288= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs377080128; called by muse, mutect2, varscan2
- KLK12 | c.186C>T p.H62= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- LARP6 | c.1089G>T p.P363= | Silent (SNP) | VAF 55/157 reads (35%) | catalogued as COSV100150721; called by muse, mutect2, varscan2
- NLRP3 | c.834C>T p.C278= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs533145119; called by muse, mutect2, varscan2
- NRAS | c.36T>A p.G12= | Silent (SNP) | VAF 129/305 reads (42%) | catalogued as COSV54746971; called by muse, mutect2, varscan2
- PCNX2 | c.6213A>C p.S2071= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- PEG3 | c.1182T>C p.Y394= | Silent (SNP) | VAF 84/237 reads (35%) | called by muse, mutect2, varscan2
- SCAMP1 | c.405G>A p.Q135= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- SLC25A39 | c.936C>T p.A312= (on ENST00000377095 / NM_001143780.3; = p.A304= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs146744993; called by muse, mutect2, varscan2
- SYS1 | c.219C>T p.N73= | Silent (SNP) | VAF 94/216 reads (44%) | catalogued as rs777457455, COSV54782409; called by muse, mutect2, varscan2
- TPRX1 | c.345C>A p.G115= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.11232A>G p.A3744= (on ENST00000591111; = p.A3698= on NM_003319.4) | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- VAV2 | c.1398C>T p.D466= (on ENST00000371850 / NM_001134398.2; = p.D461= on NM_003371.4) | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs376060225; called by muse, mutect2, varscan2
- AC018563.1 | n.603G>A | RNA (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- ADD2 | c.*1136G>T | 3'UTR (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- AL033504.1 | n.117+76646T>C | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- ANXA5 | c.*55T>A | 3'UTR (SNP) | VAF 128/210 reads (61%) | called by muse, varscan2
- B4GALT6 | c.*1491C>A | 3'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- BRD4 | c.2159-4512G>A | Intron (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- CDH2 | c.*790G>T | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- CNPY1 | c.*746G>T | 3'UTR (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- DCHS2 | n.7054C>A | RNA (SNP) | VAF 82/259 reads (32%) | catalogued as COSV104421245, COSV61777149; called by muse, mutect2, varscan2
- DGUOK | c.*203T>G | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1293A>C | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, varscan2
- FERMT2 | c.1869+266C>A | Intron (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- FMN2 | c.4066-12388C>G | Intron (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- GABPA | c.*2680A>G | 3'UTR (SNP) | VAF 112/341 reads (33%) | called by muse, mutect2, varscan2
- GABRA2 | chr4:46249298 C>T | 3'Flank (SNP) | VAF 19/47 reads (40%) | catalogued as rs1233342885; called by muse, mutect2, varscan2
- GIGYF1 | c.-1135C>T | 5'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- GLRB | c.*841T>A | 3'UTR (SNP) | VAF 59/89 reads (66%) | called by muse, mutect2, varscan2
- GREB1 | c.*1945A>G | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- H3C10 | c.*72T>G | 3'UTR (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- HOXA7 | chr7:27153158 C>T | 3'Flank (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- JCHAIN | c.*344del | 3'UTR (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- KCNH8 | c.443-27718A>C | Intron (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- KCNMB3 | c.-501_-499dup | 5'UTR (INS) | VAF 32/130 reads (25%) | called by mutect2, pindel, varscan2
- KPNA2 | c.571+28G>C | Intron (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- KPNA5 | c.*45+2406T>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- KRT6A | c.*48G>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- LEPROT | c.*3886T>A | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- LINC00544 | n.744+22G>A | Intron (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- MCL1 | c.937-110G>A | Intron (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- MYCBPAP | c.76+756T>A | Intron (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- N6AMT1 | c.*3649G>T | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- NUDT4 | c.*218G>C | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- OCRL | c.*329C>T | 3'UTR (SNP) | VAF 97/100 reads (97%) | called by muse, mutect2, varscan2
- PARP2 | chr14:20343600 C>A | 5'Flank (SNP) | VAF 17/54 reads (31%) | catalogued as rs376933412; called by muse, mutect2, varscan2
- PFKP | c.1684-462T>C | Intron (SNP) | VAF 67/111 reads (60%) | called by muse, mutect2, varscan2
- PLA2G15 | c.502+56T>G | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PRKG1 | c.*1751T>C | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, varscan2
- PRR18 | chr6:166308402 T>G | 5'Flank (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- RBMX | chrX:136870059 A>G | 3'Flank (SNP) | VAF 192/192 reads (100%) | called by muse, mutect2, varscan2
- RBPMS | c.-317C>T | 5'UTR (SNP) | VAF 68/138 reads (49%) | called by muse, varscan2
- RNY4P14 | chr13:39788619 A>G | 5'Flank (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- SYT10 | c.*1350A>G | 3'UTR (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- TPRX2P | n.489C>T | RNA (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- TWNK | c.*810C>T | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- UBBP4 | n.1202A>T | RNA (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- USP21 | c.601-142G>A | Intron (SNP) | VAF 13/22 reads (59%) | called by muse, varscan2
- VWA5B1 | chr1:20354334 G>C | 3'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-1066A>G | 5'UTR (SNP) | VAF 38/44 reads (86%) | called by muse, mutect2, varscan2
- ZNF131 | c.-16+14A>T | Intron (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
